CGCI case BLGSP-71-19-00104 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/39f9996d-b217-4222-98ea-47c210d49e93

Demographics
Sex at birth: female; Race: white; Age at index: 14 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Intra-abdominal lymph nodes; Classification of tumor: primary; Age at diagnosis: 14.0 years (5,117 days); Year of diagnosis: 1985; Method of diagnosis: Fine Needle Aspiration; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 11,480 days (31.4 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Other; Sites of involvement: Peritoneum, NOS.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Paraaortic.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 10,850 days (29.7 years); Disease response: Tumor Free.
- Days to follow up: 11,480 days (31.4 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- Lactate Dehydrogenase 506 [Blood test normal range upper: 300].

Other clinical attributes
- Day 0: Weight: 33 kg; Height: 164 cm; BMI: 12.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-19-00104-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Frozen; Days to sample procurement: 4 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
  Slide BLGSP-71-19-00104-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
  Slide BLGSP-71-19-00104-01A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
- Sample BLGSP-71-19-00104-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00104-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen; Days to sample procurement: 9,748 days (26.7 years); Method of sample procurement: Blood Draw; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: NHL, diffuse, small noncleaved cell type (Burkitt's); Extranodal site involvement: 1; Extranodal involvment other: peritoneum; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: fine needle; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: para-aortic.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 506.
